CCDI case PBBUBL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4d267d71-aa60-4c83-9ca0-64a8001fff83

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.3 years (1,920 days).

Biospecimens (3 samples)
- Sample 0DH700: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH72R: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH73S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
